Somatic mutation profile of tumor specimen TCGA-CQ-7063-01A (aliquot TCGA-CQ-7063-01A-11D-2394-08) from TCGA case TCGA-CQ-7063, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 59.5 years (21,723 days).
Specimen TCGA-CQ-7063-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab42286-841f-492c-bade-817a338b703f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7063-10A (Blood Derived Normal), aliquot TCGA-CQ-7063-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/464d7abb-796c-4ef9-a448-c1eadcbce095

The open-access MAF lists 143 somatic variants for this specimen: 103 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 35, Splice Site 4, Nonsense Mutation 4, RNA 3, Frame Shift Del 2, 5'UTR 1, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 50/90 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAT2 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100887119; called by muse, mutect2, varscan2
- ACOT8 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1436213963, COSV99467338; called by muse, mutect2, varscan2
- ACVR2B | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1209096025, COSV100754161; called by muse, mutect2, varscan2
- ADGRB3 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100999869; called by muse, mutect2, varscan2
- AGGF1 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100461517; called by muse, mutect2, varscan2
- AHNAK | c.12275C>G p.S4092* | Nonsense Mutation (SNP) | VAF 54/260 reads (21%) | catalogued as COSV99945690; called by muse, mutect2, varscan2
- AK9 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV53421129, COSV99572348; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100628414; called by muse, mutect2, varscan2
- ARHGEF6 | c.1417T>G p.L473V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99166353; called by muse, mutect2, varscan2
- ATRX | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100970110; called by muse, mutect2, varscan2
- BTNL2 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as CM142306, COSV100895979; called by muse, varscan2
- C17orf97 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100789273; called by muse, mutect2, varscan2
- C9orf40 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1034444854, COSV100964949; called by muse, mutect2, varscan2
- CCDC172 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs750332973, COSV60938432; called by muse, mutect2, varscan2
- CHSY1 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs143549949; called by muse, mutect2, varscan2
- CLK3 | c.586C>T p.R196W (on ENST00000395066 / NM_001130028.1; = p.R48W on NM_003992.4) | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764753199, COSV100775828; called by muse, mutect2, varscan2
- CLTC | c.2143C>G p.L715V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99291744; called by muse, mutect2
- COL6A3 | c.8231C>T p.T2744M | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373680762; called by muse, mutect2, varscan2
- CORO2B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as rs543637910, COSV55955115, COSV99962909; called by muse, mutect2
- CYLC2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV100872366, COSV66336147; called by muse, mutect2
- DAAM1 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100658162; called by muse, mutect2, varscan2
- DCDC1 | c.3601G>C p.E1201Q (on ENST00000597505 / NM_001367979.1; = p.E308Q on NM_020869.3) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as COSV100337860, COSV60304556; called by muse, mutect2, varscan2
- DENND2A | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99325574; called by muse, mutect2, varscan2
- DIO2 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101375820, COSV101375984; called by muse, mutect2, varscan2
- DMD | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99919703; called by muse, mutect2, varscan2
- DMTF1 | c.2107C>A p.H703N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV99991277; called by mutect2, varscan2
- DNAH8 | c.3958C>T p.R1320C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs78877915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.2470G>A p.V824M | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.125); catalogued as rs746434765, COSV66620237; called by muse, mutect2, varscan2
- DOK5 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99373283; called by mutect2, varscan2
- DPH1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs566200844, COSV99559434; called by muse, mutect2, varscan2
- ENTPD1 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV100967376; called by muse, varscan2
- ERCC6L | c.2672G>A p.R891H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146534560, COSV57820058; called by muse, mutect2, varscan2
- EXTL1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs147835535, COSV65338529; called by muse, mutect2, varscan2
- F13A1 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs772167756, COSV53563513, COSV99342256; called by muse, mutect2, varscan2
- GFAP | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV99493070; called by muse, mutect2, varscan2
- HELB | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99921612; called by muse, mutect2, varscan2
- HIPK1 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV101060205; called by muse, mutect2, varscan2
- IKBKB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV100645594; called by muse, mutect2, varscan2
- INPPL1 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.691); catalogued as rs745724027, COSV99995868; called by muse, varscan2
- IPO7 | c.3020-1G>C p.X1007_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as COSV101121785, COSV65684806; called by muse, mutect2, varscan2
- KDM3B | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100069211; called by muse, mutect2, varscan2
- KIF21A | c.2758C>T p.R920C (on ENST00000361418 / NM_001378440.1; = p.R907C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201804365, COSV100735304; called by muse, mutect2, varscan2
- KRT75 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs370991901, COSV99359189; called by muse, mutect2
- LCMT1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as rs771771338, COSV101111603; called by muse, mutect2, varscan2
- LCT | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs757179373, COSV51544263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LETM1 | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100245232, COSV57104458; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375447132; called by muse, varscan2
- LIPG | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV54296728; called by muse, mutect2, varscan2
- LIPG | c.1377A>G p.K459= | Splice Region (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99724272; called by muse, mutect2, varscan2
- LPCAT2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142700202; called by muse, mutect2, varscan2
- LRP1B | c.2936G>C p.R979T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101252965; called by muse, mutect2, varscan2
- LRRC45 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765209623, COSV60711988; called by muse, mutect2, varscan2
- LRRK1 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.477); catalogued as COSV99437828; called by muse, mutect2, varscan2
- MACO1 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV100975019; called by muse, mutect2, varscan2
- MAP1LC3A | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as COSV54160480, COSV99465926; called by muse, mutect2, varscan2
- MCM3AP | c.3480G>C p.E1160D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99386501; called by muse, mutect2, varscan2
- MFF | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100449254; called by muse, mutect2, varscan2
- MIDEAS | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs755175254, COSV99678607; called by muse, mutect2, varscan2
- MUC6 | c.1459A>T p.I487F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs774487013, COSV101424415; called by muse, mutect2, varscan2
- MYH7 | c.5105C>T p.A1702V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs750013359, COSV100805722; called by muse, mutect2, varscan2
- NCAPD3 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157655772, COSV101596355; called by muse, mutect2, varscan2
- NLRP1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs373530609; called by muse, mutect2, varscan2
- OR52E4 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100389151, COSV57626528; called by muse, mutect2, varscan2
- PLA2G4F | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs373084106; called by muse, mutect2, varscan2
- PLEC | c.10396G>C p.E3466Q (on ENST00000322810 / NM_201380.4; = p.E3356Q on NM_000445.5) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100511044; called by muse, mutect2, varscan2
- PPP1R13L | c.1948-1G>C p.X650_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100714675; called by muse, mutect2
- PPP2R3A | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99386476; called by muse, mutect2, varscan2
- PPP4R3B | c.1565-1G>A p.X522_splice (on ENST00000616407 / NM_001122964.3; = p.X490_splice on NM_020463.4) | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99701431; called by muse, mutect2, varscan2
- PPP4R4 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs745732168, COSV58553728; called by muse, mutect2, varscan2
- PRCC | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99618454; called by muse, mutect2, varscan2
- PRUNE2 | c.2357C>A p.T786K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV100944240; called by muse, varscan2
- PTPRD | c.3851T>C p.V1284A | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100643462; called by muse, mutect2
- PTPRE | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.88); catalogued as COSV99616959; called by muse, mutect2, varscan2
- PTPRM | c.3714G>C p.E1238D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as rs1212955204, COSV100155096; called by muse, mutect2, varscan2
- PTPRZ1 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101099613, COSV66439394; called by muse, mutect2, varscan2
- PZP | c.4229C>G p.S1410C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV99736265; called by muse, mutect2, varscan2
- RGS5 | c.156-1G>C p.X52_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58351312, COSV58351978; called by mutect2, varscan2
- SENP1 | c.1227dup p.G410Rfs*3 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs750651342, COSV50304253; called by mutect2, varscan2
- SLAIN2 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99971491; called by muse, mutect2, varscan2
- SLC22A14 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs146612743; called by muse, mutect2, varscan2
- SLC35F1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs138680595, COSV64500406; called by muse, mutect2, varscan2
- SYNJ2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.443); catalogued as rs147584404; called by mutect2, varscan2
- SZT2 | c.3475C>G p.Q1159E (on ENST00000634258 / NM_001365999.1; = p.Q1102E on NM_015284.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV65171660; called by muse, mutect2, varscan2
- TBC1D7 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV100568543; called by muse, mutect2, varscan2
- TEX45 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100861791; called by muse, mutect2, varscan2
- TIRAP | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs1478302183, COSV101201554; called by muse, mutect2, varscan2
- TMC3 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100845818, COSV100845837; called by muse, mutect2, varscan2
- TNNT1 | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV99402701; called by muse, mutect2, varscan2
- TRPM3 | c.1465G>A p.E489K (on ENST00000357533 / NM_001366142.2; = p.E334K on NM_020952.6) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100676676, COSV100678844; called by muse, mutect2, varscan2
- TSKS | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV99882941; called by muse, mutect2, varscan2
- TTN | c.6685C>T p.H2229Y (on ENST00000591111; = p.H2183Y on NM_003319.4) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | PolyPhen probably damaging (0.994); catalogued as rs56851316, COSV60463348; called by muse, mutect2
- USH2A | c.6104G>T p.C2035F | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100229407; called by muse, mutect2, varscan2
- USP51 | c.1271C>A p.T424N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV101540644; called by muse, mutect2, varscan2
- VXN | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100559874, COSV59686307; called by muse, mutect2, varscan2
- ZNF438 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1262096792, COSV100061289; called by muse, mutect2, varscan2
- ZNF91 | c.3277C>G p.L1093V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV56082009; called by muse, mutect2, varscan2
- ANKRD55 | c.145del p.E49Kfs*6 | Frame Shift Del (DEL) | VAF 21/115 reads (18%) | called by mutect2, pindel, varscan2
- IGLV2-33 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- MAST4 | c.4559G>A p.R1520H (on ENST00000403625 / NM_001164664.2; = p.R1331H on NM_015183.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR5AR1 | c.33del p.E11Dfs*23 | Frame Shift Del (DEL) | VAF 42/196 reads (21%) | called by mutect2, varscan2
- WASHC2C | c.3889G>C p.D1297H (on ENST00000336378; = p.D1276H on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADD1 | c.831G>A p.L277= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99296026; called by muse, mutect2, varscan2
- ALDH3A1 | c.1299G>A p.L433= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV99855742; called by muse, mutect2, varscan2
- ARMC5 | c.48C>T p.L16= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51655029, COSV51657963, COSV51659455; called by muse, mutect2
- CBLC | c.1143G>A p.S381= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs535354110, COSV99541842; called by muse, mutect2, varscan2
- CCDC88C | c.3273C>T p.S1091= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101105146; called by muse, mutect2, varscan2
- CCT4 | c.1534C>T p.L512= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs776361122, COSV101075062; called by muse, mutect2, varscan2
- CIAO3 | c.381G>C p.R127= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99284568; called by muse, mutect2, varscan2
- CPB2 | c.633C>T p.L211= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs930139891, COSV99472952; called by muse, mutect2, varscan2
- CYP11B2 | c.1035G>C p.L345= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs780878883, COSV59997631; called by muse, mutect2, varscan2
- EIF3L | c.237C>G p.V79= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV101094442; called by muse, mutect2, varscan2
- ELAC1 | c.714C>G p.V238= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99494776; called by muse, mutect2, varscan2
- EXOSC7 | c.762G>A p.E254= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99651849; called by muse, mutect2, varscan2
- FOXD4L6 | c.846G>A p.P282= | Silent (SNP) | VAF 18/32 reads (56%) | called by mutect2, varscan2
- GALNT14 | c.456C>T p.F152= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs267599341, COSV100204097; called by muse, mutect2, varscan2
- KRT36 | c.1014C>A p.A338= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV100057351; called by muse, mutect2, varscan2
- MAP2K7 | c.828G>A p.R276= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1209200866, COSV101208980, COSV101209145; called by muse, mutect2, varscan2
- MAST1 | c.3843G>A p.A1281= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1468156704, COSV99262044, COSV99262364; called by muse, mutect2
- MCTP2 | c.1432C>T p.L478= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100537223; called by muse, mutect2, varscan2
- OSBPL1A | c.1005C>T p.Y335= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs542892857, COSV100111163; called by muse, mutect2, varscan2
- PCDHGA12 | c.987G>A p.A329= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV52766412; called by muse, mutect2, varscan2
- PLXNA3 | c.2772G>A p.T924= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as rs781801174, COSV100859817, COSV63756222; called by muse, mutect2
- RASL11A | c.728G>A p.*243= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99610983; called by muse, mutect2, varscan2
- RRAGC | c.1167G>A p.L389= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV65931511; called by muse, mutect2, varscan2
- SACS | c.9183C>G p.L3061= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101207184, COSV66541152; called by muse, mutect2, varscan2
- SAMD7 | c.879G>A p.K293= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100156754, COSV59419310; called by muse, mutect2, varscan2
- SCN1A | c.135C>T p.D45= | Silent (SNP) | VAF 31/208 reads (15%) | catalogued as rs201985242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- STX12 | c.825G>A p.T275= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV64248945; called by muse, mutect2
- STX16 | c.738C>T p.S246= (on ENST00000371141 / NM_001001433.3; = p.S225= on NM_003763.6) | Silent (SNP) | VAF 20/128 reads (16%) | called by mutect2, varscan2
- SUCO | c.1269C>T p.F423= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1288503305, COSV99741922; called by muse, mutect2, varscan2
- TENM3 | c.7629C>A p.G2543= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- TLR7 | c.1269G>C p.L423= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV101027725; called by muse, mutect2, varscan2
- TLR7 | c.1632G>C p.L544= | Silent (SNP) | VAF 90/434 reads (21%) | catalogued as COSV101027727; called by muse, mutect2, varscan2
- WNT8B | c.603C>T p.F201= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100648933; called by muse, mutect2, varscan2
- XCL1 | c.15C>T p.I5= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV100892196; called by muse, mutect2, varscan2
- ZNF490 | c.1140C>T p.H380= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs559788529, COSV61007051; called by muse, mutect2, varscan2
- C20orf197 | n.598G>A | RNA (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- GTF2H2B | n.847C>T | RNA (SNP) | VAF 22/186 reads (12%) | called by mutect2, varscan2
- H2BC4 | c.-1G>C | 5'UTR (SNP) | VAF 23/114 reads (20%) | catalogued as rs772024840, COSV100019750, COSV58417612; called by muse, mutect2, varscan2
- HERC2P3 | n.449G>A | RNA (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2, varscan2
- RAB5IF | c.*53G>C | 3'UTR (SNP) | VAF 85/408 reads (21%) | catalogued as COSV53413024, COSV99481250; called by muse, mutect2, varscan2
